CPTAC case C3L-02662 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/600ec637-0fa7-4e57-83e8-2c4149393507

Demographics
Sex at birth: male; Race: white; Year of birth: 1952; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 65.5 years (23,940 days); Year of diagnosis: 2018; Last known disease status: Tumor free; Days to last known disease status: 1,384 days (3.8 years); Progression or recurrence: no; Days to last follow up: 1,384 days (3.8 years).
   Pathology details: Greatest tumor dimension: 1.5 cm.

Follow-up (5 entries)
- Days to follow up: 427 days (1.2 years); Disease response: Tumor Free; ECOG performance status: 1.
- Days to follow up: 761 days (2.1 years); Disease response: Tumor Free; ECOG performance status: 1.
- Days to follow up: 966 days (2.6 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 966 days (2.6 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,384 days (3.8 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 75 kg; Height: 190 cm; BMI: 20.78.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 19; Cigarettes per day: 10; Tobacco smoking onset year: 1979; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 43.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02662-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 47 mg; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02662-22: Section location: Right Hemisphere; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-02662-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 50 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02662-23: Section location: Right Hemisphere; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample C3L-02662-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 33 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02662-25: Section location: Right Hemisphere; Percent tumor nuclei: 70; Percent necrosis: 15.
- Sample C3L-02662-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -16 days; Method of sample procurement: Blood Draw.
